Surgical pathology report (de-identified scan), TCGA case TCGA-A3-A8CQ, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-A8CQ-01A (Primary Tumor).

Sex: Female
D.O.B.:

SPECIMEN INFORMATION

Collected:
Received:
Reported:

Accession #:
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Left partial nephrectomy with tumor:
Carcinoma.

Tumor Characteristics:

1. Histologic type: Conventional-clear cell.
2. Tumor site: Left kidney.
3. Tumor focality: Unifocal.
4. Tumor size: 2.5 x 2 x 1.5 cm.
5. Macroscopic extent of tumor: Limited to kidney.
6. Microscopic extent of tumor: Limited to kidney.
7. Nuclear grade: Fuhrman grade 2/4.
8. Lymphovascular space invasion: Not identified.
9. Sarcomatoid features: Not identified.

Surgical Margin Status:

Margins uninvolved, tumor present approximately 0.1 cm from posterior (stitch) margin, tumor abuts capsule.

Lymph Node Status:

Total number of lymph nodes received: None.

Other:

1. Other significant findings: None.
2. pTN stage: pT1a NX.

ICD-O-3
Carcinoma, clear cell NOS 8310/3
Site: @ Kidney NOS C64.9
W 4/17/14

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Stitch on posterior margin
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

Left renal tumor/mass

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in a single formalin filled container labeled with the patient's name and "left renal tumor/mass" and consists of a 3.5 x 2.4 x 2.2 cm partial nephrectomy specimen. Red-pink, shaggy renal parenchyma is present on one aspect and it bears a stitch. The opposite aspect is smooth and encapsulated. The sutured parenchymal aspect is inked blue and the encapsulated aspect is inked blue. The specimen is sectioned to reveal a 2.5 x 2.0 x 1.5 cm, well circumscribed, yellow-tan, hemorrhagic and variegated mass that approaches to within 0.1 cm of the sutured parenchymal aspect and abuts the encapsulated aspect. The specimen is entirely submitted in cassettes 1-6 labeled. Additionally, a yellow and green cassette are submitted for genomics research, each labeled

Case is (check):		

Source: NCI Genomic Data Commons file 9c17921f-ad06-49b0-bf36-6d5bfd1ba35b (TCGA-A3-A8CQ.42951E48-270A-4DEC-98A4-2D239C009478.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).